CCDI case PBBNHP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6569eb23-41f6-43d3-9d83-55d57e8c704a

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,427 days).

Biospecimens (3 samples)
- Sample 0DD6R7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DD6RC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DD6RH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
